Somatic mutation profile of tumor specimen TCGA-NC-A5HN-01A (aliquot TCGA-NC-A5HN-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.1 years (28,151 days).
Specimen TCGA-NC-A5HN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56228077-4c93-4167-af50-b9d95be9125a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HN-10A (Blood Derived Normal), aliquot TCGA-NC-A5HN-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df26ce3c-ec30-4ff6-9450-903a77e60af2

The open-access MAF lists 647 somatic variants for this specimen: 467 protein-altering or splice-affecting, 164 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 418, Silent 164, Nonsense Mutation 20, Splice Site 15, Frame Shift Del 9, Intron 6, RNA 4, In Frame Del 3, 3'UTR 2, Frame Shift Ins 1, Splice Region 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 26/30 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2002G>A p.E668K (on ENST00000272895 / NM_173076.3; = p.E350K on NM_015657.3) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV99790171; called by muse, mutect2, varscan2
- ABCB1 | c.2752C>A p.H918N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99713144; called by muse, mutect2, varscan2
- ABCC2 | c.1573G>T p.V525L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs145924141; called by muse, mutect2, varscan2
- ABCC8 | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV100217308; called by muse, mutect2, varscan2
- ABCC8 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV100217310; called by muse, mutect2, varscan2
- AC092143.1 | c.1837T>C p.F613L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100205851; called by muse, mutect2, varscan2
- AC131160.1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV57700637; called by muse, mutect2, varscan2
- ACAN | c.2245G>T p.V749L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100718192; called by muse, mutect2, varscan2
- ACCSL | c.48A>C p.R16S | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101122201; called by muse, mutect2, varscan2
- ADAMTS17 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV99170737; called by muse, mutect2, varscan2
- ADAMTS3 | c.3581A>G p.N1194S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54387135; called by muse, mutect2, varscan2
- ADAMTS4 | c.2467C>G p.Q823E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100917763; called by muse, mutect2, varscan2
- ADAMTS5 | c.1728G>T p.W576C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99536845; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3985C>G p.P1329A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.988); catalogued as COSV99719061; called by muse, mutect2, varscan2
- ADCY3 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99568317; called by muse, mutect2, varscan2
- ADCY8 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1007898263, COSV99652509; called by muse, mutect2, varscan2
- ADGRE2 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as rs556958859, COSV100216075; called by muse, mutect2, varscan2
- ADGRF5 | c.2728G>C p.A910P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99345691; called by muse, mutect2
- ADGRV1 | c.4664C>G p.S1555W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101316026, COSV67979966; called by muse, mutect2, varscan2
- ADGRV1 | c.6193G>C p.D2065H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315287; called by muse, mutect2, varscan2
- ADPRS | c.705G>T p.L235F | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99255537; called by muse, mutect2, varscan2
- AFF1 | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100320666; called by muse, mutect2, varscan2
- AFP | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1308781257, COSV99890021; called by muse, mutect2
- AGO4 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100942970; called by muse, mutect2, varscan2
- AHCYL1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314043777, COSV100779597; called by muse, mutect2, varscan2
- ALPK3 | c.4475C>A p.A1492E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99360990, COSV99361044; called by muse, mutect2, varscan2
- ANK2 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs746628566, COSV100001831; called by muse, mutect2, varscan2
- ANKRD35 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100841744; called by muse, mutect2, varscan2
- AOAH | c.1134G>T p.G378= | Splice Region (SNP) | VAF 9/62 reads (15%) | catalogued as rs866563358, COSV51737820, COSV99331895, COSV99332906; called by muse, varscan2
- ARC | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as COSV100751719; called by muse, mutect2, varscan2
- ARHGAP17 | c.909G>T p.L303F | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99253494; called by muse, mutect2, varscan2
- ASAP1 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as COSV100727314; called by muse, mutect2, varscan2
- ATG2A | c.3985C>G p.P1329A | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101034417; called by muse, mutect2, varscan2
- ATP10A | c.3056G>C p.R1019P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100791287; called by muse, mutect2, varscan2
- ATP10A | c.847+1G>T p.X283_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100791288; called by muse, mutect2, varscan2
- ATP10A | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100791289; called by muse, mutect2, varscan2
- ATP2B1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665762; called by muse, mutect2, varscan2
- ATRX | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100970830; called by muse, mutect2, varscan2
- BARHL1 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV55037800, COSV99707596; called by muse, mutect2, varscan2
- BATF3 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV99695990; called by muse, mutect2, varscan2
- BAZ2B | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs949401310, COSV100600668; called by muse, mutect2, varscan2
- BBX | c.2638G>T p.V880F (on ENST00000325805 / NM_001142568.3; = p.V850F on NM_020235.7) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100361645; called by muse, mutect2, varscan2
- BDP1 | c.2974A>C p.I992L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100703147; called by muse, mutect2, varscan2
- BIRC3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV99679943; called by muse, mutect2, varscan2
- BLMH | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs908920732, COSV99913145; called by muse, mutect2, varscan2
- BLNK | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99813937; called by muse, mutect2, varscan2
- BPIFB1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV99487400; called by muse, mutect2, varscan2
- BRCA2 | c.9925G>A p.E3309K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs80359251, CM082512, COSV101200856; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRINP1 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 29/37 reads (78%) | catalogued as COSV99775645; called by muse, mutect2, varscan2
- BZW1 | c.1156G>T p.V386F | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as COSV100729859, COSV63349736; called by muse, mutect2, varscan2
- C1GALT1C1L | c.820A>T p.T274S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.278); catalogued as COSV56758403; called by muse, mutect2, varscan2
- C6 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV54710168, COSV54721144; called by muse, mutect2, varscan2
- CALCA | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100524029; called by muse, mutect2, varscan2
- CASR | c.2162C>A p.P721Q (on ENST00000490131; = p.P798Q on NM_000388.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM124140, COSV56135853, COSV99949011; called by muse, mutect2, varscan2
- CCAR1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.401); catalogued as COSV99771076; called by muse, mutect2, varscan2
- CCDC171 | c.2107C>A p.H703N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1224684173, COSV99900910; called by muse, mutect2, varscan2
- CCT5 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV99725364; called by muse, mutect2, varscan2
- CD72 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as COSV99427469; called by muse, mutect2, varscan2
- CD72 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99427472; called by muse, mutect2, varscan2
- CDC42BPB | c.597-5_597-2del p.X199_splice | Splice Site (DEL) | VAF 14/116 reads (12%) | catalogued as rs768769729; called by mutect2, pindel
- CDH12 | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV101202637, COSV66397017; called by muse, mutect2, varscan2
- CDRT1 | c.2195G>T p.G732V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100599885; called by muse, mutect2, varscan2
- CENPJ | c.2669A>G p.N890S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1194740975, COSV101121516; called by muse, mutect2
- CEP126 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99681085; called by muse, mutect2, varscan2
- CEP89 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99993513; called by muse, mutect2, varscan2
- CFAP44 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV99869634; called by muse, mutect2, varscan2
- CHD4 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs747906347, COSV100538111; called by muse, mutect2, varscan2
- CHRM5 | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271956; called by muse, mutect2, varscan2
- CHTF18 | c.2270T>C p.L757P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99242988; called by mutect2, varscan2
- CIP2A | c.1245G>C p.R415S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99842919; called by muse, mutect2, varscan2
- CIZ1 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99476906; called by muse, mutect2, varscan2
- CLMN | c.1892C>G p.P631R | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as COSV54184394; called by muse, mutect2, varscan2
- CNGB3 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100182064, COSV60694956; called by muse, mutect2, varscan2
- CNTN6 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100610795, COSV100610903; called by muse, mutect2, varscan2
- COBL | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.459); catalogued as COSV99472754; called by muse, mutect2, varscan2
- COL1A2 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51957655, COSV99799861; called by muse, mutect2, varscan2
- COL2A1 | c.1834-1G>A p.X612_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100476559; called by muse, mutect2, varscan2
- COL5A1 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); catalogued as COSV100880019; called by muse, mutect2, varscan2
- COL5A1 | c.4658C>G p.P1553R | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100880020; called by muse, mutect2, varscan2
- COLEC12 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101232076; called by muse, mutect2, varscan2
- COPA | c.884G>A p.W295* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99615732; called by muse, mutect2, varscan2
- CPEB1 | c.709G>A p.D237N (on ENST00000617958; = p.D177N on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV99917728; called by muse, mutect2, varscan2
- CRAMP1 | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99561719; called by muse, mutect2, varscan2
- CRB1 | c.860A>T p.N287I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV100958937, COSV66339069; called by muse, mutect2, varscan2
- CRB1 | c.2482G>T p.D828Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100957898, COSV100958021; called by muse, mutect2, varscan2
- CSMD3 | c.10096A>G p.T3366A (on ENST00000297405 / NM_001363185.1; = p.T3197A on NM_052900.3) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV52226785, COSV99033699; called by muse, mutect2, varscan2
- CTDSP2 | c.708G>C p.W236C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101143006; called by muse, mutect2, varscan2
- CTDSPL | c.486T>G p.F162L (on ENST00000273179 / NM_001008392.2; = p.F151L on NM_005808.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99828735; called by muse, mutect2, varscan2
- CTNNA2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777032066, COSV63569988, COSV63590877; called by muse, mutect2, varscan2
- CTSF | c.1178G>T p.W393L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100074299; called by muse, mutect2, varscan2
- CYLC1 | c.421A>T p.N141Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV100254709; called by muse, varscan2
- CYP2U1 | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV100256713; called by muse, mutect2, varscan2
- CYP8B1 | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs1365210121, COSV100296167, COSV60227445; called by muse, mutect2, varscan2
- CYP8B1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60225918; called by muse, mutect2, varscan2
- DAGLA | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.987); catalogued as rs758107539, COSV99944423; called by muse, mutect2, varscan2
- DCC | c.1400C>A p.S467Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500357; called by muse, mutect2
- DDX21 | c.1669-1G>C p.X557_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100826520; called by muse, mutect2, varscan2
- DDX54 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013922; called by muse, mutect2, varscan2
- DDX60L | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99487669; called by muse, mutect2, varscan2
- DEFB127 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101213839; called by muse, mutect2, varscan2
- DENND1A | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.1); catalogued as COSV101011998; called by muse, mutect2, varscan2
- DIAPH3 | c.2522A>C p.E841A (on ENST00000400324 / NM_001042517.2; = p.E578A on NM_030932.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933635; called by muse, mutect2, varscan2
- DNA2 | c.1940T>A p.V647E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100622596; called by muse, mutect2, varscan2
- DNAAF4 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1425693640, COSV100336745; called by muse, mutect2, varscan2
- DNAH7 | c.6723G>T p.M2241I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100415366; called by muse, mutect2, varscan2
- DNAH8 | c.3611T>C p.F1204S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100545563; called by muse, mutect2, varscan2
- DNHD1 | c.1720T>G p.C574G | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV99600194; called by muse, mutect2, varscan2
- DOCK7 | c.4862A>G p.K1621R (on ENST00000635253 / NM_001367561.1; = p.K1590R on NM_033407.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV99224630; called by muse, mutect2, varscan2
- DOP1A | c.4523C>G p.A1508G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV52710572; called by muse, mutect2, varscan2
- DPP6 | c.1183G>C p.A395P (on ENST00000377770 / NM_001364500.2; = p.A333P on NM_001936.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100125862; called by muse, mutect2, varscan2
- DPPA3 | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61502798; called by muse, mutect2, varscan2
- DPPA4 | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as COSV100169451, COSV59509951; called by muse, mutect2, varscan2
- DRD3 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as COSV99879462; called by muse, mutect2, varscan2
- DSC1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99937695; called by muse, mutect2, varscan2
- DYNC1H1 | c.11276G>A p.R3759H | Missense Mutation (SNP) | VAF 99/181 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV64138629; called by muse, mutect2, varscan2
- DYSF | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 38/43 reads (88%) | catalogued as COSV99247450; called by muse, mutect2, varscan2
- EBF1 | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100565850, COSV100566053; called by muse, mutect2, varscan2
- EBF2 | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV101282191; called by muse, mutect2, varscan2
- EBI3 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99696072; called by muse, mutect2, varscan2
- EML1 | c.1753-1G>C p.X585_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV99215077; called by muse, mutect2, varscan2
- EN2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV99818634; called by muse, mutect2, varscan2
- ENG | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100785294; called by muse, mutect2
- ENPP3 | c.1985C>A p.P662Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV100717354; called by muse, mutect2, varscan2
- EPHA3 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100345551, COSV60733254; called by muse, mutect2, varscan2
- EPS8 | c.1199G>C p.G400A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1046453549, COSV99843211; called by muse, mutect2, varscan2
- ERV3-1 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); catalogued as COSV99275728; called by muse, mutect2, varscan2
- ETV1 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV99623570; called by muse, mutect2, varscan2
- F13B | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100803300; called by muse, mutect2
- FABP1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV99860847, COSV99860895; called by muse, mutect2, varscan2
- FAM133A | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100220206, COSV100220410; called by muse, mutect2, varscan2
- FAM214A | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99958011; called by muse, mutect2
- FAM71B | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 58/152 reads (38%) | catalogued as COSV100262093, COSV100262130; called by muse, mutect2, varscan2
- FAM91A1 | c.72+1G>C p.X24_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100593606; called by muse, mutect2, varscan2
- FAM91A1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.164); catalogued as COSV100593607; called by muse, mutect2, varscan2
- FAT2 | c.6367G>A p.G2123R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55830162; called by muse, mutect2, varscan2
- FAT4 | c.3239T>A p.L1080H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101272364; called by muse, mutect2, varscan2
- FBF1 | c.526A>T p.K176* (on ENST00000586717; = p.K190* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100045191; called by muse, mutect2, varscan2
- FCRL5 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708979; called by muse, mutect2, varscan2
- FCRLA | c.747G>C p.Q249H (on ENST00000367959; = p.Q226H on NM_032738.4) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV99376088; called by muse, mutect2, varscan2
- FLRT3 | c.785T>A p.V262E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99433692; called by muse, mutect2, varscan2
- FLT1 | c.1834A>G p.T612A | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.257); catalogued as COSV99159429; called by muse, mutect2, varscan2
- FO393400.1 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.511); catalogued as COSV99640709; called by muse, mutect2, varscan2
- FO393400.1 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV99640711; called by muse, mutect2, varscan2
- FOXF2 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs181428616, COSV52525311; called by muse, mutect2, varscan2
- FRMPD2 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100563858; called by muse, mutect2, varscan2
- GAB4 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV101271866, COSV68753910; called by muse, mutect2, varscan2
- GALNT1 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs745396196, COSV52455739; called by muse, mutect2, varscan2
- GALNT13 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV101223110; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GEMIN5 | c.913G>T p.G305* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV99593951; called by muse, mutect2, varscan2
- GJB6 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV99576075; called by muse, mutect2, varscan2
- GLRB | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100029772, COSV52422006; called by muse, mutect2, varscan2
- GLS2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100358367, COSV100358371; called by muse, mutect2, varscan2
- GNPAT | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs773375326, COSV100791631; called by mutect2, varscan2
- GPC5 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100994183; called by muse, mutect2, varscan2
- GRIN3A | c.2931G>T p.Q977H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100701528; called by muse, mutect2, varscan2
- GRM3 | c.2233G>T p.V745L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.457); catalogued as COSV100862580; called by muse, mutect2, varscan2
- H3-5 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as rs777192061, COSV61188215; called by muse, mutect2, varscan2
- HACE1 | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99493784; called by muse, mutect2, varscan2
- HCN1 | c.2017C>A p.L673M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.347); catalogued as COSV100300467, COSV57504016; called by muse, varscan2
- HECW2 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV99647333; called by muse, mutect2, varscan2
- HELZ | c.2280A>T p.E760D | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV100698751; called by muse, mutect2, varscan2
- HOXA9 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100604361, COSV100604395; called by muse, mutect2
- HOXC8 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 162/274 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV104377812, COSV99236845; called by muse, mutect2, varscan2
- HOXD10 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as rs886055157, COSV99982770; called by muse, mutect2, varscan2
- HPD | c.1140C>A p.N380K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770550811, COSV100000110; called by muse, mutect2, varscan2
- HTR1E | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100541119; called by muse, mutect2, varscan2
- HYDIN | c.12323T>A p.I4108N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101125097; called by muse, mutect2, varscan2
- IGKV3D-20 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs962653533; called by muse, mutect2, varscan2
- IGLV1-44 | c.150T>G p.S50R | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs547043398; called by muse, mutect2, varscan2
- IL12RB2 | c.2234A>G p.H745R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV99255179; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1928T>A p.I643K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV100147306; called by muse, mutect2, varscan2
- ILDR2 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99613932; called by muse, mutect2
- ILDR2 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99613935; called by muse, mutect2, varscan2
- INA | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878632; called by muse, mutect2, varscan2
- INSRR | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100947562; called by muse, mutect2, varscan2
- INTS5 | c.2549G>T p.R850L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV100399644; called by muse, mutect2, varscan2
- IPO8 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV99805368; called by muse, mutect2, varscan2
- IQGAP3 | c.1828G>C p.A610P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs952150571, COSV100752160; called by muse, mutect2, varscan2
- ISM2 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); catalogued as COSV99376664; called by muse, mutect2, varscan2
- ITGA10 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.275); catalogued as COSV100994926; called by muse, mutect2, varscan2
- ITGAM | c.1756C>T p.Q586* (on ENST00000648685 / NM_001145808.2; = p.Q585* on NM_000632.4) | Nonsense Mutation (SNP) | VAF 39/190 reads (21%) | catalogued as COSV54939211; called by muse, mutect2, varscan2
- ITGB8 | c.2191A>G p.K731E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as COSV99751573; called by muse, mutect2, varscan2
- ITLN1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs754389543, COSV58274520; called by muse, mutect2, varscan2
- JADE2 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV99253286; called by muse, mutect2, varscan2
- KCNIP3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs370915474; called by muse, mutect2, varscan2
- KIAA0100 | c.3280A>T p.T1094S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV101197324; called by muse, mutect2, varscan2
- KIDINS220 | c.4406A>T p.D1469V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV99875768; called by muse, mutect2, varscan2
- KIDINS220 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99875770; called by muse, mutect2, varscan2
- KIF20B | c.4438C>T p.R1480* (on ENST00000371728 / NM_001284259.2; = p.R1440* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs376548512, COSV99590983; called by muse, mutect2, varscan2
- KIF5C | c.1400A>C p.Q467P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68483145; called by muse, mutect2
- KLHL2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as rs1413708402, COSV99899790, COSV99899978; called by muse, mutect2, varscan2
- KLHL20 | c.1150A>G p.R384G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.716); catalogued as COSV99268431; called by muse, mutect2, varscan2
- KLK4 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.584); catalogued as rs926460878, COSV100133641; called by muse, mutect2, varscan2
- KMT2D | c.2332T>C p.C778R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs905939046, COSV56409025; called by muse, mutect2, varscan2
- KMT2E | c.3988C>G p.P1330A | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV99996384; called by muse, mutect2, varscan2
- KRT10 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99510091; called by muse, mutect2, varscan2
- KRT38 | c.662A>G p.K221R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.83); catalogued as rs1456227739, COSV99878230; called by muse, mutect2, varscan2
- LAMA2 | c.7876G>C p.V2626L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV101370495; called by muse, mutect2, varscan2
- LAMB3 | c.2408G>A p.G803D | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100620366; called by muse, mutect2, varscan2
- LAMB4 | c.4724A>G p.Q1575R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99224192; called by muse, mutect2, varscan2
- LAMP5 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99855597; called by muse, mutect2, varscan2
- LCE2B | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs575837944, COSV64227423; called by muse, mutect2, varscan2
- LCLAT1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092669, COSV58371296; called by muse, mutect2, varscan2
- LDHAL6B | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV99895672; called by muse, mutect2, varscan2
- LEPR | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756584; called by muse, mutect2, varscan2
- LIG4 | c.2241C>A p.C747* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100799921; called by muse, mutect2, varscan2
- LILRB2 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV100079354; called by muse, mutect2, varscan2
- LNPK | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV99770211; called by muse, mutect2
- LONRF1 | c.1204C>G p.P402A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV101238222; called by muse, mutect2, varscan2
- LRP2 | c.12902G>T p.G4301V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55577254, COSV99788647; called by muse, mutect2
- LRP2 | c.12901G>A p.G4301R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99788648; called by muse, mutect2
- LRRN4CL | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV99628256; called by muse, mutect2, varscan2
- LTBP1 | c.1018G>C p.A340P | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100617243; called by muse, mutect2, varscan2
- LUZP1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760779821, COSV100034977; called by muse, mutect2, varscan2
- LY86 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100041038; called by muse, mutect2, varscan2
- MACROD2 | c.1019A>T p.K340I (on ENST00000642719; = p.K312I on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); catalogued as COSV99433694; called by muse, mutect2, varscan2
- MAN1A1 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63787130; called by muse, mutect2, varscan2
- MAP2K3 | c.477G>T p.M159I (on ENST00000342679 / NM_145109.3; = p.M130I on NM_002756.4) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100383942; called by muse, mutect2
- MAP3K20 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100169138; called by muse, mutect2, varscan2
- MAST4 | c.6770A>G p.Q2257R (on ENST00000403625 / NM_001164664.2; = p.Q2068R on NM_015183.3) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); catalogued as COSV99844354; called by muse, mutect2, varscan2
- MEI1 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100300017; called by muse, mutect2, varscan2
- MFSD6 | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV99855206; called by muse, mutect2, varscan2
- MGAM | c.4790G>A p.W1597* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as COSV101527515; called by muse, mutect2, varscan2
- MS4A14 | c.1831G>C p.A611P | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as COSV100280468; called by muse, mutect2, varscan2
- MTNR1B | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV99925131; called by muse, mutect2, varscan2
- MTUS2 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV101462249; called by muse, mutect2, varscan2
- MUC17 | c.9259C>A p.P3087T | Missense Mutation (SNP) | VAF 113/358 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100073468; called by muse, mutect2, varscan2
- MYBPC1 | c.2101G>A p.G701S (on ENST00000550270 / NM_206820.2; = p.G726S on NM_002465.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100638036; called by muse, mutect2, varscan2
- MYH1 | c.2368A>T p.T790S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99876041; called by muse, mutect2, varscan2
- MYH4 | c.3600C>A p.H1200Q | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs1366797907, COSV99701114, COSV99701369; called by muse, varscan2
- MYH7 | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs730880732, CM983829, COSV100806153; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MYO6 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100889359, COSV64121430; called by muse, mutect2, varscan2
- MYOM3 | c.4158G>T p.R1386S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100141743; called by muse, mutect2, varscan2
- NAV2 | c.1170C>G p.H390Q (on ENST00000396087 / NM_001244963.2; = p.H367Q on NM_145117.5) | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100586311; called by muse, mutect2, varscan2
- NAV3 | c.5033G>T p.S1678I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99891462; called by muse, mutect2, varscan2
- NBAS | c.5962A>G p.S1988G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99869952; called by muse, mutect2, varscan2
- NBEA | c.5437G>T p.A1813S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100080616; called by muse, mutect2, varscan2
- NCAN | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 67/209 reads (32%) | catalogued as COSV99387284; called by muse, mutect2, varscan2
- NCKAP1 | c.3203A>T p.K1068I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100720276; called by muse, mutect2, varscan2
- NCKAP1 | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1250178441, COSV100720278; called by muse, mutect2, varscan2
- NCOA1 | c.3854G>T p.W1285L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99946168; called by muse, mutect2, varscan2
- NCOA4 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs781848770; called by muse, mutect2, varscan2
- NCSTN | c.1348A>T p.N450Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667177; called by muse, mutect2, varscan2
- NDC80 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs752108431, COSV55246775, COSV99859681; called by muse, mutect2, varscan2
- NDRG3 | c.899G>A p.G300E (on ENST00000349004 / NM_032013.4; = p.G288E on NM_022477.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100675386; called by muse, mutect2, varscan2
- NDST2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs774706715, COSV100014023; called by muse, mutect2, varscan2
- NDST4 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99996604; called by muse, mutect2, varscan2
- NDUFV1 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100295328; called by muse, mutect2, varscan2
- NELL1 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100121717, COSV54335057; called by muse, mutect2, varscan2
- NFIA | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100963954; called by muse, mutect2, varscan2
- NLRC3 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV100072851, COSV57095220; called by muse, mutect2
- NOS3 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99871693; called by muse, mutect2, varscan2
- NRG3 | c.1055-2A>C p.X352_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100931616, COSV64584472; called by muse, mutect2, varscan2
- NRXN1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1342441489, COSV101277633; called by muse, mutect2, varscan2
- NSD1 | c.5032G>A p.G1678R | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729201, COSV100729954; called by muse, mutect2, varscan2
- NUP155 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs914631348, COSV99192924; called by muse, mutect2, varscan2
- NUTM2F | c.807C>G p.N269K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99480150; called by muse, mutect2, varscan2
- NVL | c.2213G>A p.G738D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99894399; called by muse, mutect2, varscan2
- OCRL | c.772T>A p.L258I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100843454; called by muse, mutect2, varscan2
- OGDH | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV99758943; called by muse, mutect2, varscan2
- OGDHL | c.1861+1G>A p.X621_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100934339; called by muse, mutect2, varscan2
- OLIG3 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62988809; called by muse, mutect2
- OPA1 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100655339, COSV62479176; called by muse, mutect2, varscan2
- OPHN1 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100830471; called by muse, varscan2
- OPRL1 | c.938G>T p.C313F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100402096; called by muse, mutect2, varscan2
- OR10G9 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100901620; called by muse, mutect2, varscan2
- OR2M5 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63546139; called by muse, mutect2, varscan2
- OR2T34 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs777882650, COSV60900252; called by muse, mutect2
- OR4A16 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100125091; called by muse, mutect2, varscan2
- OR4C13 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV101634190, COSV73648750; called by muse, varscan2
- OR56A4 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100417575; called by muse, mutect2, varscan2
- OR5A2 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV100119754; called by muse, mutect2, varscan2
- OR5F1 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV99558661; called by muse, mutect2, varscan2
- OR5M1 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV101591559, COSV73202120; called by muse, mutect2, varscan2
- OR6F1 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100129224, COSV57468921; called by muse, mutect2, varscan2
- OR8I2 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100136091; called by muse, mutect2, varscan2
- OR9A2 | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100628233; called by muse, mutect2, varscan2
- OR9G1 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100380423; called by muse, varscan2
- OTOF | c.4649C>A p.S1550Y (on ENST00000272371 / NM_194248.3; = p.S783Y on NM_004802.4) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99717808; called by muse, mutect2, varscan2
- OTUD4 | c.782A>G p.Y261C (on ENST00000447906 / NM_001366057.1; = p.Y196C on NM_001102653.1) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316613471, COSV99669135; called by muse, mutect2, varscan2
- OVGP1 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100868144; called by muse, mutect2, varscan2
- PARP14 | c.4473G>C p.K1491N | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV101506286; called by muse, mutect2, varscan2
- PCDH18 | c.3029_3030insC p.V1011Cfs*15 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as COSV100787332; called by mutect2, pindel, varscan2
- PCDHA3 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65366692; called by muse, mutect2, varscan2
- PCDHB7 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); catalogued as COSV99177003; called by muse, mutect2, varscan2
- PCDHB9 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs782269167, COSV53380744; called by muse, mutect2, varscan2
- PDE11A | c.2646+2T>G p.X882_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99612597; called by muse, mutect2, varscan2
- PDP1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV52601659, COSV99892001; called by muse, mutect2, varscan2
- PDZD7 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99827495; called by muse, mutect2, varscan2
- PFKL | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753870736, COSV100827169; called by muse, mutect2, varscan2
- PKHD1L1 | c.9844del p.V3282Lfs*8 | Frame Shift Del (DEL) | VAF 38/177 reads (21%) | catalogued as COSV65736199; called by mutect2, pindel, varscan2
- PLCB1 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571206; called by muse, mutect2, varscan2
- PLEK | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV99310995; called by muse, mutect2, varscan2
- PLEKHS1 | c.428C>T p.S143L (on ENST00000369310 / NM_182601.1; = p.S149L on NM_024889.5) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV100613131; called by muse, mutect2, varscan2
- POU4F2 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV99850566; called by muse, mutect2, varscan2
- PPP1R3A | c.2809G>T p.A937S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV99493046; called by muse, mutect2, varscan2
- PPP2R2A | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60099378; called by muse, mutect2, varscan2
- PRAMEF14 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100577286; called by muse, mutect2, varscan2
- PRB2 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 96/508 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.866); catalogued as COSV101231421; called by muse, varscan2
- PRDM16 | c.57T>A p.N19K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV99576187, COSV99576909; called by muse, mutect2, varscan2
- PRDM9 | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.083); catalogued as rs112001060, COSV57006728, COSV57010936; called by muse, mutect2, varscan2
- PRODH2 | c.595A>T p.S199C (on ENST00000301175; = p.S123C on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs936500292, COSV99995333; called by muse, mutect2
- PRSS58 | c.571T>A p.C191S | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101616132; called by muse, mutect2, varscan2
- PSD3 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV100496310; called by muse, mutect2, varscan2
- PTGER4 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100201567; called by muse, mutect2
- PTGS1 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs775618916, COSV56292901, COSV99793222; called by muse, mutect2, varscan2
- PTPRN2 | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV101234495; called by muse, mutect2, varscan2
- PUM1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99928122; called by muse, mutect2, varscan2
- PYGO2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.431); catalogued as COSV100868941; called by muse, mutect2
- RAB22A | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV99720261; called by muse, mutect2, varscan2
- RAP2B | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 155/347 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV100058958; called by muse, mutect2, varscan2
- RBM19 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV99926144; called by muse, mutect2, varscan2
- RBM27 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99506200; called by muse, mutect2, varscan2
- RBM6 | c.1103A>G p.D368G | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV99805482; called by muse, mutect2, varscan2
- RC3H2 | c.3248A>T p.Q1083L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100605642; called by muse, mutect2, varscan2
- RET | c.2825G>C p.W942S | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951129, COSV100393687; called by muse, mutect2, varscan2
- RFPL2 | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.681); catalogued as COSV50710314; called by muse, mutect2, varscan2
- ROR1 | c.1085G>A p.C362Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935259; called by muse, mutect2, varscan2
- RP1 | c.637A>T p.I213F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV99607615; called by muse, mutect2, varscan2
- RP1 | c.2985T>G p.I995M | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as COSV99607618; called by muse, mutect2, varscan2
- RPL10 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99185986; called by muse, mutect2, varscan2
- RTL1 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.082); catalogued as COSV101128320; called by muse, mutect2, varscan2
- RTL9 | c.3641A>G p.E1214G | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV101511695; called by muse, mutect2, varscan2
- RTTN | c.4006G>T p.E1336* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV55343145; called by muse, mutect2, varscan2
- RXYLT1 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99706917; called by mutect2, varscan2
- RYR1 | c.11779-1G>A p.X3927_splice | Splice Site (SNP) | VAF 39/114 reads (34%) | catalogued as COSV62102872; called by muse, mutect2, varscan2
- SALL1 | c.2831T>A p.I944N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99174178; called by muse, mutect2, varscan2
- SALL1 | c.1807A>G p.R603G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs575669269, COSV99174183; called by muse, mutect2, varscan2
- SAMD9L | c.2268G>T p.W756C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100560752; called by muse, mutect2
- SAMD9L | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100560753, COSV59082524; called by muse, mutect2, varscan2
- SCEL | c.1293C>G p.D431E (on ENST00000349847 / NM_144777.3; = p.D411E on NM_003843.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as COSV100582952; called by muse, mutect2, varscan2
- SCLT1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV99828112; called by muse, mutect2, varscan2
- SCN1A | c.4199T>C p.I1400T (on ENST00000303395 / NM_001202435.3; = p.I1389T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV57687600; called by muse, mutect2, varscan2
- SCN2A | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99331878; called by muse, mutect2, varscan2
- SCN4A | c.5086G>T p.A1696S | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.183); catalogued as rs769365503, COSV101438412, COSV101438497; called by muse, mutect2, varscan2
- SERPINA12 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100369704; called by muse, mutect2, varscan2
- SETD1A | c.3870G>T p.R1290S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV99353054; called by muse, mutect2, varscan2
- SEZ6L2 | c.1646C>T p.P549L (on ENST00000308713 / NM_001114099.3; = p.P479L on NM_012410.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as rs1465195091, COSV100435466; called by muse, mutect2, varscan2
- SFMBT2 | c.1137C>A p.D379E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100739109; called by muse, mutect2, varscan2
- SGSM1 | c.2259C>G p.I753M (on ENST00000400359 / NM_001039948.4; = p.I692M on NM_133454.3) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV100771869, COSV63082796; called by muse, mutect2, varscan2
- SI | c.3856A>T p.R1286* | Nonsense Mutation (SNP) | VAF 40/183 reads (22%) | catalogued as COSV100015694; called by muse, mutect2, varscan2
- SI | c.1872G>T p.L624F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100015696; called by muse, mutect2, varscan2
- SIDT1 | c.2414C>A p.S805* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99334003; called by muse, mutect2, varscan2
- SIM1 | c.1160A>T p.Y387F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492405; called by muse, mutect2, varscan2
- SLC10A5 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as COSV101594256; called by muse, mutect2
- SLC11A1 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV99262156; called by muse, mutect2, varscan2
- SLC12A9 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99307856; called by muse, mutect2, varscan2
- SLC13A4 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100818873; called by muse, mutect2
- SLC17A6 | c.1696C>A p.Q566K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1475267484, COSV99581530; called by muse, mutect2, varscan2
- SLC18A3 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340213; called by muse, mutect2, varscan2
- SLC27A2 | c.1627T>C p.F543L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99982860; called by muse, mutect2, varscan2
- SLC4A8 | c.1904+2T>A p.X635_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100176974; called by muse, mutect2, varscan2
- SLC6A1 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as rs1370388144, COSV99822789; called by muse, mutect2, varscan2
- SLC8A1 | c.2914G>A p.G972S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV60470357; called by muse, mutect2
- SLC9C1 | c.613+2T>A p.X205_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV59886267, COSV99998051; called by muse, mutect2
- SLCO4A1 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99414782; called by muse, mutect2, varscan2
- SNAPC4 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV100047272; called by muse, mutect2, varscan2
- SNPH | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100378191; called by muse, mutect2, varscan2
- SNX2 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs748065975, COSV101075700; called by muse, mutect2, varscan2
- SORBS1 | c.793G>A p.G265R (on ENST00000361941 / NM_001034954.2; = p.G233R on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1218725856, COSV53358653, COSV99528092; called by muse, mutect2, varscan2
- SP4 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.956); catalogued as COSV99754518; called by muse, mutect2, varscan2
- SP8 | c.65G>T p.S22I (on ENST00000361443 / NM_198956.4; = p.S40I on NM_182700.6) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV100815364; called by muse, mutect2, varscan2
- SPAG17 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs774289091, COSV100309237; called by muse, mutect2, varscan2
- SPAM1 | c.1400C>G p.A467G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV99773073; called by muse, mutect2, varscan2
- SPATA17 | c.717A>T p.Q239H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV100861159; called by muse, mutect2
- SPEF2 | c.4162G>A p.V1388I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100289077; called by muse, mutect2, varscan2
- SPRY1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100201843; called by muse, mutect2, varscan2
- SRRM2 | c.5489G>A p.S1830N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV100070870; called by muse, mutect2, varscan2
- SRSF6 | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99719728; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 36/306 reads (12%) | PolyPhen benign (0.093); catalogued as COSV99398497; called by muse, mutect2, varscan2
- STARD13 | c.2972A>G p.D991G (on ENST00000336934 / NM_001243476.3; = p.D873G on NM_052851.3) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as COSV99715946; called by muse, mutect2, varscan2
- SVEP1 | c.8093T>C p.I2698T | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs377400709; called by muse, mutect2, varscan2
- TARS2 | c.2099T>G p.V700G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100681994; called by muse, mutect2, varscan2
- TBC1D31 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99782770; called by muse, mutect2, varscan2
- TBX20 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057524359, COSV101282384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCERG1 | c.2996A>G p.K999R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99694944; called by muse, mutect2
- TCHH | c.4673G>T p.R1558L | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs756033778, COSV100915134, COSV100915493; called by muse, mutect2, varscan2
- TCHH | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.24); catalogued as COSV100915136; called by muse, mutect2, varscan2
- TDRD5 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99676329; called by muse, mutect2
- TDRD6 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV100287682; called by muse, mutect2, varscan2
- TET3 | c.4357G>A p.G1453S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs773211622, COSV101327860; called by muse, mutect2, varscan2
- TFAP2D | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99145944; called by muse, mutect2, varscan2
- TGFB2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100860198; called by muse, mutect2, varscan2
- TM4SF4 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); catalogued as COSV100541886; called by muse, mutect2, varscan2
- TMEM167A | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101546690; called by muse, mutect2, varscan2
- TMEM200C | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778993065, COSV67309481; called by muse, mutect2, varscan2
- TMEM255A | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100550376; called by muse, mutect2, varscan2
- TMEM52B | c.35C>G p.A12G (on ENST00000381923 / NM_001079815.1; = p.P7A on NM_153022.4) | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100046440; called by muse, mutect2, varscan2
- TNKS | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100127094; called by muse, mutect2, varscan2
- TNN | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV99512055; called by muse, mutect2, varscan2
- TNPO3 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs745576236, COSV99602998; called by muse, mutect2, varscan2
- TRAK2 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV60273706; called by muse, mutect2, varscan2
- TRDMT1 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100003959; called by muse, mutect2
- TRIP4 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs773018211, COSV99974617; called by muse, mutect2, varscan2
- TSHZ2 | c.2869A>G p.T957A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as COSV100296160; called by muse, mutect2, varscan2
- TSHZ3 | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99551742; called by muse, mutect2, varscan2
- TTBK1 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99444642; called by muse, mutect2, varscan2
- TTC30A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs140497773; called by muse, mutect2, varscan2
- TTLL7 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV99552478; called by muse, mutect2, varscan2
- TTLL7 | c.839T>A p.F280Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.194); catalogued as COSV99552480; called by muse, mutect2, varscan2
- TTN | c.41069C>T p.T13690I (on ENST00000591111; = p.T6266I on NM_003319.4) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | PolyPhen possibly damaging (0.894); catalogued as COSV100615081; called by muse, mutect2, varscan2
- TTN | c.16993G>A p.E5665K (on ENST00000591111; = p.E4738K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | PolyPhen possibly damaging (0.6); catalogued as COSV60312201; called by muse, mutect2, varscan2
- TUBB2A | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV100373898; called by muse, mutect2, varscan2
- TUSC1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772172120, COSV100787840; called by muse, varscan2
- UBE3A | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV99217328; called by muse, mutect2
- UGT3A1 | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 34/242 reads (14%) | catalogued as COSV99954445, COSV99954809; called by muse, mutect2, varscan2
- UNC5D | c.1435T>A p.S479T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99775598, COSV99779924; called by muse, mutect2, varscan2
- UNC5D | c.2395A>G p.T799A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99775599; called by muse, mutect2, varscan2
- USP5 | c.1103A>G p.D368G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99978657; called by muse, mutect2, varscan2
- USP9X | c.5866A>G p.M1956V | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100199343; called by muse, mutect2, varscan2
- UTP20 | c.8078C>T p.S2693F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs760164413, COSV99881706; called by muse, mutect2, varscan2
- VAV2 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100895830; called by muse, mutect2
- VCAN | c.7138C>A p.Q2380K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV54102801; called by muse, mutect2, varscan2
- VPS13C | c.6293C>G p.S2098C (on ENST00000644861 / NM_020821.3; = p.S2055C on NM_017684.5) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs144073158, COSV99828600; called by muse, mutect2
- VWA7 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV100791816; called by muse, mutect2, varscan2
- WAC | c.1563G>C p.Q521H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100611038; called by muse, mutect2, varscan2
- WDPCP | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as rs939729364, COSV55433541; called by muse, mutect2, varscan2
- WDR48 | c.1252A>C p.N418H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100176590; called by muse, mutect2, varscan2
- WIPF1 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV99768745; called by muse, mutect2, varscan2
- WNK4 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV99890435; called by muse, mutect2, varscan2
- WT1 | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV100188210; called by muse, mutect2, varscan2
- XIRP2 | c.7570C>G p.P2524A (on ENST00000628543; = p.P2699A on NM_152381.6) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99743376; called by muse, mutect2, varscan2
- ZEB2 | c.3610G>T p.D1204Y | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100356115; called by muse, mutect2, varscan2
- ZFHX4 | c.1361T>A p.L454* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99263205; called by muse, mutect2
- ZFHX4 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.288); catalogued as COSV99261085; called by muse, mutect2
- ZFP30 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100665931; called by muse, mutect2, varscan2
- ZFR2 | c.1573C>A p.Q525K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV99507446; called by muse, mutect2, varscan2
- ZIM2 | c.647-1G>T p.X216_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99689125; called by muse, mutect2, varscan2
- ZNF223 | c.42del p.V15Wfs*22 | Frame Shift Del (DEL) | VAF 41/147 reads (28%) | catalogued as COSV71571949; called by mutect2, pindel, varscan2
- ZNF254 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs974448279, COSV100741646, COSV61644495; called by muse, mutect2, varscan2
- ZNF300 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV99199887; called by muse, mutect2, varscan2
- ZNF383 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100776760, COSV61939717; called by muse, mutect2, varscan2
- ZNF451 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100674922; called by muse, mutect2, varscan2
- ZNF548 | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs759419376, COSV60241739; called by mutect2, varscan2
- ZNF607 | c.1642C>G p.L548V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100777895; called by muse, mutect2
- ZNF681 | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101267476; called by muse, mutect2, varscan2
- ZNF785 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV101235697; called by muse, mutect2, varscan2
- ZNF804A | c.3387A>T p.Q1129H | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100168160; called by muse, mutect2, varscan2
- ZSCAN31 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100717000; called by muse, mutect2
- ZSWIM2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV54577573; called by muse, mutect2, varscan2
- ZZZ3 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100890334; called by muse, mutect2, varscan2
- ANKMY1 | c.2154_2168del p.A719_L723del | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- C16orf82 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CFAP74 | c.4586C>T p.P1529L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DDX43 | c.1393A>C p.I465L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2
- DOP1A | c.3244_3246delinsTT p.S1083Vfs*21 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by pindel, varscan2*
- FCGBP | c.10327G>A p.E3443K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNL1 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- IGHG4 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 19/464 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2
- IGKV6D-41 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IKBKB | c.1794_1814del p.I598_V605delinsM | In Frame Del (DEL) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- MROH2B | c.2132A>G p.H711R | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.478); called by muse, mutect2
- NR1I2 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- OR4C11 | c.906del p.I304Lfs*12 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- OTUD7A | c.992A>G p.D331G (on ENST00000307050 / NM_001382637.1; = p.D324G on NM_130901.3) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIGZ | c.933_945del p.H312Lfs*39 | Frame Shift Del (DEL) | VAF 37/343 reads (11%) | called by mutect2, pindel
- RELN | c.9072_9080del p.F3025_I3027del | In Frame Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- ROCK2 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- RTCB | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A3 | c.1180A>G p.N394D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLITRK3 | c.406_421del p.K136Efs*11 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- TRAV1-1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR7 | c.4352del p.P1451Lfs*54 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- ZFX | c.2306_2309del p.I769Tfs*26 | Frame Shift Del (DEL) | VAF 39/51 reads (76%) | called by mutect2, pindel, varscan2
- ZNF676 | c.1464del p.A489Pfs*41 (on ENST00000650058; = p.A457Pfs*41 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by pindel, varscan2
- ABCB9 | c.57C>T p.C19= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs144091918; called by muse, mutect2, varscan2
- ABCG4 | c.147C>A p.R49= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100266792; called by muse, mutect2, varscan2
- AC242842.3 | c.303T>C p.S101= | Silent (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- ACAD10 | c.1839G>A p.P613= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs781233913, COSV100564231, COSV58156390; called by muse, mutect2, varscan2
- ACAN | c.2646C>T p.F882= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV61357525; called by muse, mutect2, varscan2
- ADGRB3 | c.1287A>T p.A429= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV101000837; called by muse, mutect2, varscan2
- ADGRG2 | c.2964C>T p.N988= (on ENST00000379869 / NM_001079858.3; = p.N985= on NM_005756.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs369376664, COSV61340860; called by muse, mutect2, varscan2
- ADGRL3 | c.1491C>A p.T497= (on ENST00000506720 / NM_001322402.2; = p.T429= on NM_015236.6) | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV72230065; called by muse, mutect2
- AFAP1L2 | c.1557G>A p.E519= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100412582; called by muse, mutect2, varscan2
- AGMO | c.216T>C p.A72= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs767472454, COSV100694224; called by muse, mutect2, varscan2
- AHNAK2 | c.2386C>T p.L796= | Silent (SNP) | VAF 70/581 reads (12%) | catalogued as COSV100317644, COSV60920962; called by muse, mutect2, varscan2
- ALKBH2 | c.624C>A p.S208= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV99980399; called by muse, mutect2, varscan2
- ALPK1 | c.3579A>G p.T1193= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV99454169; called by muse, mutect2, varscan2
- ANKRD30A | c.714A>T p.G238= (on ENST00000611781; = p.G182= on NM_052997.2) | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV100653607, COSV100654635; called by muse, mutect2, varscan2
- APOA1 | c.546G>C p.A182= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99369283; called by muse, mutect2, varscan2
- ARHGEF12 | c.618A>T p.V206= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100754946; called by muse, mutect2, varscan2
- BNC2 | c.3201C>T p.V1067= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV101036182; called by muse, mutect2, varscan2
- BSX | c.657C>T p.D219= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV58005106; called by muse, mutect2
- C10orf53 | c.393C>A p.T131= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100935061; called by muse, mutect2, varscan2
- C7 | c.900G>T p.G300= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100495872, COSV100496638; called by muse, mutect2, varscan2
- CAPN12 | c.1620T>C p.S540= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99400272; called by muse, mutect2, varscan2
- CASP2 | c.858G>A p.V286= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100131010; called by muse, mutect2, varscan2
- CCDC158 | c.1185G>C p.L395= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV101187253; called by muse, mutect2
- CCDC170 | c.1722G>A p.L574= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV99498480; called by muse, mutect2, varscan2
- CCDC63 | c.1134C>T p.V378= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100370395; called by muse, mutect2, varscan2
- CCNY | c.192G>T p.R64= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99590633; called by muse, mutect2, varscan2
- CD1C | c.477C>T p.A159= | Silent (SNP) | VAF 84/319 reads (26%) | catalogued as COSV100939397; called by muse, mutect2, varscan2
- CDYL2 | c.792G>C p.L264= | Silent (SNP) | VAF 47/56 reads (84%) | catalogued as COSV101629568; called by muse, mutect2, varscan2
- CEACAM8 | c.354A>T p.G118= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- CGNL1 | c.762G>A p.G254= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV99848384; called by muse, mutect2, varscan2
- CHD9 | c.6219A>T p.I2073= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99529197; called by muse, mutect2, varscan2
- CLIP3 | c.1126C>A p.R376= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV99431091; called by muse, mutect2, varscan2
- COLEC12 | c.1194T>G p.S398= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV101232077; called by muse, mutect2, varscan2
- DCC | c.1119T>A p.P373= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100500356; called by muse, mutect2, varscan2
- DHRS12 | c.126C>A p.V42= (on ENST00000444610 / NM_001377930.1; = p.S21Y on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV54472473, COSV99523861; called by muse, mutect2, varscan2
- DNAH8 | c.633A>G p.K211= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1435634863, COSV100545560; called by muse, mutect2, varscan2
- DTX2 | c.177G>T p.L59= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs764404421, COSV100184624; called by muse, mutect2, varscan2
- ECEL1 | c.1320C>A p.V440= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100458752, COSV58814161; called by muse, mutect2, varscan2
- ERCC3 | c.339G>C p.V113= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99573374; called by muse, mutect2
- EXOC2 | c.1899G>A p.K633= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100033678; called by muse, mutect2, varscan2
- EXOC6 | c.1284G>T p.L428= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99591985; called by muse, mutect2, varscan2
- FAM149A | c.1038C>A p.V346= (on ENST00000356371 / NM_001367768.2; = p.V55= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV99906565; called by muse, mutect2, varscan2
- FAM71A | c.939T>A p.A313= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs747469221, COSV99674636; called by muse, mutect2, varscan2
- FAT3 | c.3858C>A p.G1286= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV99966591; called by muse, mutect2, varscan2
- FOXD4L3 | c.87C>A p.V29= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- GALR1 | c.282C>A p.T94= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV55317952; called by muse, mutect2, varscan2
- GNL1 | c.1014G>A p.V338= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV100925424; called by muse, mutect2, varscan2
- GOLGA6L9 | c.282A>G p.L94= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- GOLGB1 | c.9090C>G p.L3030= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV61461964; called by muse, mutect2, varscan2
- GPR15 | c.510G>C p.L170= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV52520225, COSV99423771; called by muse, mutect2, varscan2
- GREB1 | c.4464C>A p.T1488= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV99302987; called by muse, mutect2, varscan2
- HAL | c.1515C>T p.A505= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99701453; called by muse, mutect2, varscan2
- HCN1 | c.2109C>T p.V703= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100300463; called by muse, varscan2
- HCN1 | c.261C>A p.P87= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100300469; called by muse, varscan2
- HIVEP1 | c.7101A>G p.L2367= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV101045168; called by muse, mutect2, varscan2
- HOXA6 | c.297C>A p.P99= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99762325; called by muse, mutect2, varscan2
- HOXD13 | c.258C>A p.S86= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV101184279; called by muse, mutect2, varscan2
- IDO2 | c.1119T>A p.P373= (on ENST00000389060; = p.P386= on NM_194294.2) | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV100584773; called by muse, mutect2, varscan2
- IGKV1D-8 | c.66T>C p.C22= | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, varscan2
- ITGA10 | c.1584C>A p.G528= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100994925; called by muse, mutect2, varscan2
- ITIH5 | c.2184C>G p.P728= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs543300408, COSV99904731, COSV99904745; called by muse, mutect2, varscan2
- JCAD | c.1227A>G p.A409= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV100948380; called by muse, mutect2, varscan2
- KCNG2 | c.1044C>A p.G348= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs368420806; called by muse, mutect2, varscan2
- KCNH7 | c.3537A>T p.V1179= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as COSV100148144; called by muse, mutect2, varscan2
- KLHL4 | c.735G>A p.L245= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV100909638; called by muse, mutect2, varscan2
- KSR1 | c.1545T>A p.P515= (on ENST00000644974 / NM_001367810.1; = p.P400= on NM_014238.2) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99259668; called by muse, mutect2, varscan2
- LCA5L | c.342T>C p.V114= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV99903648; called by muse, mutect2, varscan2
- LCTL | c.69G>A p.R23= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100427216; called by muse, mutect2, varscan2
- LRCH4 | c.252C>G p.P84= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs200187564, COSV53827147; called by muse, mutect2, varscan2
- LRP2 | c.7230A>C p.P2410= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV99788652; called by muse, mutect2
- LTBP3 | c.789C>T p.P263= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100099727; called by muse, mutect2
- LZTS3 | c.1992C>T p.R664= (on ENST00000329152; = p.R618= on NM_001282533.2) | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as COSV99417986; called by muse, mutect2, varscan2
- MALT1 | c.483C>T p.F161= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100618720; called by muse, mutect2, varscan2
- MAP3K7 | c.33C>G p.S11= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs760655014, COSV100997937; called by muse, varscan2
- MARK1 | c.2387A>G p.*796= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100857277; called by muse, mutect2, varscan2
- MATN2 | c.2373T>G p.A791= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV99646386; called by muse, mutect2, varscan2
- MBD5 | c.180C>T p.C60= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101290103; called by muse, mutect2, varscan2
- MCM2 | c.468G>A p.R156= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99413173; called by muse, mutect2
- MGAT5 | c.1905C>T p.L635= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs1422827261, COSV56101563; called by muse, mutect2, varscan2
- MORF4L1 | c.900A>G p.P300= (on ENST00000331268 / NM_206839.2; = p.P261= on NM_006791.4) | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100489131; called by muse, mutect2, varscan2
- MORN1 | c.969C>T p.P323= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV101047474; called by muse, mutect2, varscan2
- MRPL9 | c.669G>A p.V223= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100162544; called by muse, mutect2
- MYO3B | c.1239T>C p.F413= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100510412; called by muse, mutect2
- NACC2 | c.417C>T p.G139= | Silent (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- NBEA | c.5826G>C p.L1942= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV100080619, COSV59829142; called by muse, mutect2, varscan2
- NCKAP1 | c.54C>T p.T18= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100720280; called by muse, mutect2
- NCOA2 | c.1089A>G p.E363= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV101475993; called by muse, mutect2, varscan2
- NFATC3 | c.2952G>A p.G984= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100285254; called by muse, mutect2, varscan2
- NLRP3 | c.1068G>A p.L356= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV60222149; called by muse, mutect2, varscan2
- NLRP4 | c.810C>G p.L270= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV100016361; called by muse, mutect2, varscan2
- NPAP1 | c.412A>C p.R138= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100275459; called by muse, mutect2, varscan2
- NPC1L1 | c.960G>A p.K320= | Silent (SNP) | VAF 34/213 reads (16%) | catalogued as COSV56930144; called by muse, mutect2, varscan2
- NWD1 | c.1443G>T p.R481= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs373890312, COSV60342393; called by muse, mutect2, varscan2
- NWD1 | c.3762C>T p.T1254= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV100342723; called by muse, mutect2, varscan2
- OLFM3 | c.477G>T p.V159= (on ENST00000338858 / NM_001288821.1; = p.V139= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV58802119; called by muse, mutect2, varscan2
- OLFML2B | c.1695C>G p.G565= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV99668484; called by muse, mutect2, varscan2
- OPCML | c.330A>G p.E110= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs934941764, COSV100099862, COSV59434500; called by muse, mutect2, varscan2
- OR10R2 | c.711T>C p.S237= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100936794; called by muse, mutect2
- OR2M5 | c.237C>A p.P79= | Silent (SNP) | VAF 102/351 reads (29%) | catalogued as COSV100822819, COSV100822863; called by muse, mutect2, varscan2
- OR4B1 | c.48C>T p.F16= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV58884042; called by muse, mutect2, varscan2
- OR4C13 | c.48A>T p.T16= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV101634193; called by muse, varscan2
- OR4K2 | c.588C>A p.G196= | Silent (SNP) | VAF 114/341 reads (33%) | catalogued as COSV100064497; called by muse, mutect2, varscan2
- OR5B2 | c.513G>T p.L171= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100222892; called by muse, mutect2, varscan2
- OR5D16 | c.84C>A p.P28= | Silent (SNP) | VAF 54/100 reads (54%) | catalogued as COSV65722905; called by muse, mutect2
- OR5H2 | c.843C>A p.V281= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs200543339, COSV100788738, COSV100788832; called by muse, mutect2, varscan2
- OR5W2 | c.339A>G p.L113= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100747641; called by muse, mutect2, varscan2
- OR9G4 | c.471A>T p.I157= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100265135; called by muse, mutect2, varscan2
- PCDHA11 | c.1908G>A p.L636= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1408586283, COSV100250838; called by muse, mutect2, varscan2
- PCDHA7 | c.2073C>G p.T691= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs563748429, COSV100970776, COSV100970809, COSV65335403; called by muse, mutect2, varscan2
- PDCD11 | c.2928C>T p.V976= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100874351; called by muse, mutect2, varscan2
- PDHA2 | c.585C>T p.G195= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs550687466, COSV54777335, COSV54777456; called by muse, mutect2, varscan2
- PDLIM7 | c.729G>A p.L243= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100730238; called by muse, mutect2, varscan2
- PDZD2 | c.6315T>C p.C2105= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as COSV99225150; called by muse, mutect2, varscan2
- PHEX | c.1195T>C p.L399= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV101039657; called by muse, mutect2, varscan2
- PIWIL1 | c.2550A>C p.P850= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV99806449; called by muse, mutect2, varscan2
- PPP1R26 | c.1128G>A p.Q376= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV100778074; called by muse, mutect2, varscan2
- PRKAR2B | c.456C>A p.I152= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1562865572, COSV99708298; called by muse, mutect2, varscan2
- PSG7 | c.444A>G p.K148= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as rs755154025, COSV68445580; called by muse, mutect2, varscan2
- PXYLP1 | c.813G>A p.L271= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV99649494; called by muse, mutect2, varscan2
- PYGB | c.750C>G p.P250= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV99405119; called by muse, mutect2, varscan2
- ROR2 | c.1236C>T p.I412= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs752218712, COSV100995848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCG3 | c.579A>G p.V193= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99590962; called by muse, mutect2, varscan2
- SCN1A | c.1296C>T p.A432= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100320553; called by muse, mutect2, varscan2
- SCUBE3 | c.280C>A p.R94= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99234523; called by muse, mutect2, varscan2
- SEC24B | c.1038A>T p.P346= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99493613; called by muse, mutect2, varscan2
- SERPINE3 | c.618C>T p.D206= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV101246448; called by muse, mutect2, varscan2
- SLAMF1 | c.192C>A p.V64= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV52498505, COSV99349324; called by muse, mutect2, varscan2
- SLC24A5 | c.24A>T p.T8= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100415155; called by muse, mutect2, varscan2
- SLC25A23 | c.864G>A p.L288= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99902248; called by muse, mutect2, varscan2
- SLC26A5 | c.1992A>G p.V664= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs769588977, COSV100099371; called by muse, mutect2, varscan2
- SLC29A4 | c.381G>A p.V127= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs774864187, COSV99786811; called by muse, mutect2, varscan2
- SLITRK3 | c.2559T>A p.T853= | Silent (SNP) | VAF 33/241 reads (14%) | catalogued as COSV99579322; called by muse, mutect2, varscan2
- SMAD1 | c.153G>T p.L51= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100129760, COSV57470679; called by muse, mutect2, varscan2
- SMARCA2 | c.1230C>G p.L410= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs771891440, COSV100571138; called by muse, mutect2, varscan2
- SPA17 | c.309C>T p.I103= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99907140; called by muse, mutect2
- SPATA31E1 | c.3162G>A p.R1054= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs201156365, COSV100350514, COSV57789342; called by muse, mutect2, varscan2
- SPEF2 | c.3540C>A p.I1180= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100607552; called by muse, mutect2, varscan2
- SRRM2 | c.2202C>T p.S734= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100070869; called by muse, mutect2, varscan2
- ST13 | c.67C>T p.L23= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV99344196; called by muse, mutect2, varscan2
- ST3GAL1 | c.243C>T p.T81= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100172121; called by muse, mutect2, varscan2
- SYNE1 | c.19533G>T p.L6511= (on ENST00000367255 / NM_182961.4; = p.L6440= on NM_033071.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99565909; called by muse, mutect2, varscan2
- TENT5D | c.201A>T p.V67= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100382771; called by muse, mutect2, varscan2
- TEX15 | c.2016T>A p.I672= (on ENST00000256246; = p.I1055= on NM_001350162.2) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99821407; called by muse, mutect2
- TG | c.5835G>A p.Q1945= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99601060; called by muse, mutect2, varscan2
- TGM7 | c.469C>T p.L157= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101476863; called by muse, mutect2, varscan2
- TIMM44 | c.126C>T p.G42= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs755914550, COSV54490990; called by muse, mutect2, varscan2
- TMPRSS6 | c.2097C>T p.G699= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1488283715, COSV100695450; called by muse, mutect2, varscan2
- TPO | c.525A>G p.R175= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV100221195; called by muse, mutect2, varscan2
- TSHR | c.1476T>A p.P492= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99991947; called by muse, mutect2, varscan2
- TSN | c.648C>A p.G216= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as COSV101067503; called by muse, mutect2, varscan2
- TTN | c.75177C>A p.A25059= (on ENST00000591111; = p.A17635= on NM_003319.4) | Silent (SNP) | VAF 37/200 reads (19%) | catalogued as COSV100615067; called by muse, mutect2, varscan2
- TTN | c.48249A>G p.G16083= (on ENST00000591111; = p.G8659= on NM_003319.4) | Silent (SNP) | VAF 64/487 reads (13%) | catalogued as COSV100615074; called by muse, mutect2, varscan2
- TTN | c.15882T>C p.S5294= (on ENST00000591111; = p.S4367= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV100615084; called by muse, mutect2, varscan2
- UBE2M | c.87G>C p.A29= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99285258; called by muse, mutect2, varscan2
- VNN1 | c.738A>T p.S246= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100907734; called by muse, mutect2, varscan2
- VSIR | c.852C>A p.T284= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs767886762, COSV99821195; called by muse, mutect2, varscan2
- WNT2B | c.952C>T p.L318= (on ENST00000369684 / NM_024494.3; = p.L299= on NM_004185.4) | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV99861701; called by muse, mutect2, varscan2
- WNT9A | c.753C>G p.L251= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as rs1489934940, COSV99688278; called by muse, mutect2
- ZDHHC19 | c.234A>T p.S78= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99579618; called by muse, mutect2, varscan2
- ZNF280B | c.618T>C p.D206= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs1332599601, COSV100840317; called by muse, mutect2, varscan2
- ZNF318 | c.4179A>G p.K1393= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100546198; called by muse, mutect2, varscan2
- ZNF608 | c.600C>G p.G200= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100101755; called by muse, mutect2, varscan2
- ZNF7 | c.1974G>C p.G658= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV100295892; called by muse, mutect2, varscan2
- ZNF804A | c.1377T>A p.P459= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100168156; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83224G>A | Intron (SNP) | VAF 225/281 reads (80%) | catalogued as rs201243951; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208209 G>T | 5'Flank (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- CCDC140 | n.531T>G | RNA (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99735122; called by muse, mutect2, varscan2
- DSCR4 | n.449G>T | RNA (SNP) | VAF 22/90 reads (24%) | catalogued as rs1331497757, COSV100077326; called by muse, mutect2, varscan2
- FMN1 | c.2044-2485G>T | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100568744; called by muse, mutect2, varscan2
- GGT5 | c.-2C>A | 5'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99571570; called by muse, varscan2
- MACROD2 | c.418+165047A>G | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs760096539; called by muse, varscan2
- MFSD4B | c.*666G>T | 3'UTR (SNP) | VAF 32/78 reads (41%) | catalogued as rs769821901, COSV100920594, COSV64349388; called by muse, mutect2, varscan2
- MIR1206 | n.55C>A | RNA (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- OBSCN | c.4585+2611A>T | Intron (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99478829; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+762A>G | Intron (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99195770; called by muse, mutect2, varscan2
- PTER | c.*1G>T | 3'UTR (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100126680, COSV100126831; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2900G>A | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- SARDH | c.1020+264C>T | Intron (SNP) | VAF 35/250 reads (14%) | catalogued as COSV100897979; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827784 C>T | 3'Flank (SNP) | VAF 18/31 reads (58%) | catalogued as COSV59428513; called by muse, mutect2, varscan2
- Unknown | chr21:16194633 G>T | IGR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
